Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0TD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0TD-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: [REDACTED]
Med Rec No: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]
Pt. Phone no: [REDACTED]

Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Atypical endometrial hyperplasia, postmenopausal bleeding

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

A: Uterus, cervix
B: Left pelvic lymph nodes
C: Right pelvic lymph nodes
D: Bilateral tubes and ovaries

1C0-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Path Site: Endometrium C54.1
CQC corpus uteri C54.9
10/27/11

DIAGNOSIS:

A. Uterus, cervix:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	Total abdominal hysterectomy with bilateral salphingo-oophorectomy and pelvic lymph node dissection
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 1
Nuclear grade:	2
Tumor size:	3.5 x 2.0 x 0.3 cm
Extent of invasion:	Less than 1/2 of myometrium (1mm of invasion)
Lympho/vascular invasion:	Absent
Serosa:	Uninvolved by tumor
Parametrium:	Uninvolved by tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Other findings:	Adenomyosis
Special studies:	NA
Staging information:	T1b,N0, MX; stage IA if M0

B. Left pelvic lymph nodes: 0 of 5 lymph nodes negative for metastasis
C. Right pelvic lymph nodes: 0 of 8 lymph nodes negative of metastasis
D. Bilateral tubes and ovaries: No evidence of malignancy

Supplementary Statement:

The following statement may be applicable to most of the foregoing information used in developing the above report. This was developed and all pathologists should create a statement to be reviewed and approved by the U.S. Food and Drug Administration. The FDA has determined that the use of the word "adenocarcinoma" is not necessary. It should not be required as a condition of research. This statement is provided under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

Intraoperative Consultation:

Frozen Section Interpretation: Endometrial adenocarcinoma with foci suspicious for myometrial invasion

Gross Description

A. Received: Fresh soft tan to pink tissue
Labeled: Uterus and cervix
Weight: 210 gm
Size:
Uterus: 11.1 x 8.3 x 4.9 cm
Appearance
Tumor Location: Anterior wall of uterine body
Size: 3.5 x 2.0 x 0.3 cm
Appearance: Granular, tan to pink, with no obvious areas of necrosis-
Depth of invasion: Superficial, appears to not invade the upper one half of specimen
Invasion of contiguous structures: None grossly identified
Distance from margins: 5.4 cm from the surgical margin
Cervix: Smooth, shaggy, white with no lesions grossly identified
Endometrium: 0.2 cm, smooth, shiny, with areas of hemorrhage and mucoid material, with the exception in the above noted in tumor
Myometrium: 3.0 cm in thickness, with possible diffuse areas of adenomyosis, largest up to 3.0 x 2.8 x 2.5 cm
Lymph nodes: None grossly identified
Special studies: None

KEY TO CASSETTES:

A1 - Frozen section
A2 - Cervix
A3-A7 - Endomyometrium, full thickness, cassettes 3&4 one section each, bisected
A8-A14 - Endomyometrium
A15 - Parametrium (left parametrium inked blue)
A16 - Representative of possible adenomyosis

- B. Received in formalin labeled "left pelvic lymph node" are four pieces of soft tan to yellow tissue, 6 grams, aggregating up to 3.4 x 2.7 x 1.5 cm. There are five lymph nodes grossly identified, largest up to 1.5 x 0.6 x 0.4 cm, inked blue. Submitted in toto in two cassettes with cassette B1 containing five lymph nodes (largest inked blue) and rest of specimen in B2.
- C. Received in formalin labeled "right pelvic lymph node" are two pieces of soft tan to yellow tissue, 9 grams, aggregating up to 4.5 x 3.6 x 1.5 cm. There are seven lymph nodes grossly identified, largest up to 2.7 x 1.4 x 0.6 cm (inked blue). Submitted in toto in four cassettes as follows:

KEY TO CASSETTES:

C1 - Two lymph nodes (largest inked blue)
C2 - Two lymph nodes (one inked orange and unstained)
C3 - Three lymph nodes
C4 - Rest of specimen

- D. Received in formalin labeled "bilateral tubes and ovaries" are two pieces of unoriented soft tan to white tissue, 14 grams, aggregating up to 5.4 x 5.2 x 1.4 cm. The right ovary measures 2.6 x 2.2 x 0.6 cm. The left ovary measures 2.0 x 1.6 x 0.5 cm. The right tube measures 5.0 x 0.5 x 0.4 cm and is grossly unremarkable. No paratubal cystic structures are grossly identified. The left tube measures 2.5 x 0.4 x 0.4 cm, is grossly unremarkable with no paratubal cystic structures grossly identified. The cut surface of the right ovary is homogenous, tan to white. The cut surface of the left ovary is homogenous white. Representative sections are submitted in two cassettes with the cassette D1 containing right adnexa (unstained) and cassette D2 containing left adnexa (inked blue)

[page 3 of 3]
Microscopic Description

A-D. The microscopic findings support the above diagnoses.

[REDACTED]

Source: NCI Genomic Data Commons file 68a55970-d474-4187-83f5-ab322bab52ae (TCGA-BS-A0TD.51ABEFF0-EEA1-48CA-9E00-CC57D1A2DEB0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).